Somatic mutation profile of tumor specimen C3L-01606-01 (aliquot CPT0086260009) from CPTAC case C3L-01606, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.7 years (24,376 days).
Specimen C3L-01606-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01eae796-47a7-4955-a380-7f868701fd10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01606-31 (Blood Derived Normal), aliquot CPT0087360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b64c7047-8f36-4ee0-b6a2-9aebeecd257e

The open-access MAF lists 379 somatic variants for this specimen: 244 protein-altering or splice-affecting, 90 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 90, Intron 22, Nonsense Mutation 15, 5'UTR 7, RNA 7, Frame Shift Del 6, 3'UTR 6, Splice Site 3, 5'Flank 3, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HGF | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 59/364 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV55949342, COSV55956077; called by muse, varscan2
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 64/315 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.3318A>C p.E1106D (on ENST00000265723 / NM_018849.3; = p.E1099D on NM_000443.4) | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV55933483; called by muse, mutect2, varscan2
- ACTG2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.529); catalogued as COSV61829147; called by muse, mutect2, varscan2
- ACTN1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1261292195, COSV51996482; called by muse, mutect2, varscan2
- AFF3 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1352670162, COSV57866483; called by muse, mutect2, varscan2
- AHNAK2 | c.8620G>A p.A2874T | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV60924961; called by muse, mutect2, varscan2
- ALDH1L2 | c.2540G>C p.R847P | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51552607; called by muse, mutect2
- AP1B1 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201912976; called by muse, mutect2, varscan2
- ARID2 | c.4438G>C p.G1480R | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as rs587778056; ClinVar: not provided; called by muse, mutect2, varscan2
- ATP2A1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100837277; called by muse, mutect2, varscan2
- ATXN7L2 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs199625357; called by muse, mutect2, varscan2
- BRINP1 | c.1774C>G p.L592V | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.522); catalogued as COSV56292112, COSV56302727; called by muse, mutect2, varscan2
- CALN1 | c.314T>C p.L105P (on ENST00000329008 / NM_001017440.3; = p.L147P on NM_031468.4) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61148100; called by muse, mutect2, varscan2
- CCDC150 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 32/250 reads (13%) | catalogued as COSV55873546; called by muse, mutect2, varscan2
- CCDC33 | c.2056G>C p.E686Q | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99166282; called by muse, mutect2, varscan2
- CFAP54 | c.7834C>T p.Q2612* | Nonsense Mutation (SNP) | VAF 20/124 reads (16%) | catalogued as rs772789276; called by muse, mutect2, varscan2
- CFH | c.2137G>C p.D713H | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV66412078; called by muse, mutect2, varscan2
- CHRNA4 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 91/702 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1369167310; called by muse, mutect2, varscan2
- CNTRL | c.3655G>A p.D1219N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.321); catalogued as COSV53045357; called by muse, mutect2
- CPS1 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs777233486, CM063924; called by muse, mutect2, varscan2
- DCC | c.3928C>T p.P1310S | Missense Mutation (SNP) | VAF 58/511 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs267605210; called by muse, mutect2, varscan2
- DIDO1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs770549757, COSV56623373, COSV56627673; called by muse, mutect2, varscan2
- DNAH8 | c.9005C>G p.S3002C | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs770273303; called by muse, mutect2
- DNAJC22 | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101222611; called by muse, mutect2
- DPYS | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 68/630 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV60912098; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs536698371; called by muse, mutect2, varscan2
- EIF2AK3 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs900837802; called by muse, mutect2, varscan2
- FAM234B | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 29/250 reads (12%) | catalogued as COSV52196751; called by muse, mutect2, varscan2
- FMO5 | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs782678465, COSV54205745; called by muse, mutect2, varscan2
- FRZB | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 45/280 reads (16%) | catalogued as rs993235624; called by muse, mutect2, varscan2
- GABRA2 | c.1026G>T p.W342C | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV62911384; called by muse, mutect2, varscan2
- GKN2 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV61031142; called by muse, mutect2, varscan2
- GPR37 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV58255747; called by muse, mutect2, varscan2
- GPR6 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as rs1330554584; called by muse, mutect2, varscan2
- GRIN2B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.726); catalogued as rs201377003, COSV74205072; ClinVar: likely benign; called by muse, mutect2, varscan2
- H3-5 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV61188309; called by muse, mutect2, varscan2
- HCN1 | c.1830C>A p.N610K | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV57504856, COSV57532956; called by muse, varscan2
- HEY1 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as COSV61233746; called by muse, mutect2, varscan2
- IFI16 | c.2278-1G>T p.X760_splice (on ENST00000295809 / NM_001364867.2; = p.X704_splice on NM_005531.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as rs758545387, COSV55533971; called by muse, mutect2, varscan2
- IGF2R | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV100807125; called by muse, mutect2, varscan2
- ITGAM | c.2066G>T p.R689L (on ENST00000648685 / NM_001145808.2; = p.R688L on NM_000632.4) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs771862568; called by muse, mutect2
- KRTAP19-6 | c.34G>T p.G12* | Nonsense Mutation (SNP) | VAF 23/138 reads (17%) | catalogued as rs372000798; called by muse, mutect2, varscan2
- LOXHD1 | c.197C>A p.T66K | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV104437551, COSV71599936; called by muse, mutect2
- MAP3K7 | c.1556C>G p.S519C (on ENST00000369329 / NM_145331.3; = p.S492C on NM_003188.4) | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs955925138; called by muse, mutect2, varscan2
- MGA | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 32/215 reads (15%) | catalogued as COSV54951855, COSV54954625; called by muse, mutect2, varscan2
- MUC16 | c.3607C>A p.P1203T | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as COSV67501607; called by muse, mutect2, varscan2
- MYBPC1 | c.2887A>G p.I963V (on ENST00000550270 / NM_206820.2; = p.I970V on NM_002465.4) | Missense Mutation (SNP) | VAF 68/489 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); catalogued as rs749155247; called by muse, mutect2, varscan2
- NAXD | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs755306024; called by muse, mutect2, varscan2
- NIN | c.5080G>A p.D1694N (on ENST00000382041 / NM_182946.1; = p.D981N on NM_016350.4) | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs764626410, COSV55399915; called by muse, mutect2, varscan2
- NLRP8 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); catalogued as COSV52586776; called by mutect2, varscan2
- NUTM2A | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.134); catalogued as rs1286665918; called by mutect2, varscan2
- OAS2 | c.1922C>A p.P641H | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60803409; called by muse, mutect2, varscan2
- OR2A1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 82/1288 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV101283410; called by muse, mutect2
- OTOG | c.4913G>A p.G1638D | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1565116431; called by muse, mutect2, varscan2
- PANX3 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.58); catalogued as COSV52511333; called by muse, mutect2, varscan2
- PARD3B | c.186T>A p.D62E | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62508600; called by muse, mutect2, varscan2
- PCDHA3 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 60/462 reads (13%) | catalogued as COSV100793053; called by muse, mutect2, varscan2
- PCLO | c.6614G>A p.S2205N | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); catalogued as rs1035966951, COSV61658974; called by muse, mutect2
- PDE4B | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV58482324; called by muse, mutect2, varscan2
- PDZD8 | c.3239C>T p.S1080L | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53688544; called by muse, mutect2, varscan2
- PIEZO2 | c.6931C>T p.R2311C | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99554974, COSV99554992; called by muse, mutect2, varscan2
- PLEC | c.10189G>A p.E3397K (on ENST00000322810 / NM_201380.4; = p.E3287K on NM_000445.5) | Missense Mutation (SNP) | VAF 68/636 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs908922450; called by muse, mutect2, varscan2
- PPP4C | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221956; called by muse, mutect2, varscan2
- PRB2 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs768807460, COSV66983346; called by muse, varscan2
- PREX1 | c.2786G>T p.S929I | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as rs752267649; called by muse, mutect2, varscan2
- PRKCQ | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.353); catalogued as rs757898311, COSV54120724; called by muse, mutect2, varscan2
- PSMD1 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.899); catalogued as COSV58075856; called by muse, mutect2
- RFX6 | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV60588163; called by muse, mutect2, varscan2
- RXFP1 | c.1112A>G p.H371R | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV57047310; called by muse, mutect2, varscan2
- SCAPER | c.764G>C p.R255P | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.626); catalogued as rs771125619, COSV57739669, COSV57740127; called by muse, varscan2
- SELENOI | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99564613; called by muse, mutect2, varscan2
- SLC35F3 | c.694G>A p.V232I (on ENST00000366617 / NM_001300845.1; = p.V301I on NM_173508.4) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.23); catalogued as rs373070068; called by muse, mutect2, varscan2
- SLC36A4 | c.1358A>G p.N453S | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs1203063592; called by muse, mutect2, varscan2
- SLC9B2 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as rs1238475997; called by muse, mutect2, varscan2
- SPHKAP | c.2764G>C p.D922H | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100764743; called by muse, mutect2, varscan2
- STK31 | c.3027G>T p.K1009N | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.82); catalogued as COSV63455247; called by muse, mutect2, varscan2
- SYT2 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66141234; called by muse, mutect2, varscan2
- TMEM132E | c.571C>G p.P191A (on ENST00000321639; = p.P281A on NM_001304438.2) | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV58700495; called by muse, mutect2, varscan2
- TSC1 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748845915; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- VNN3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV51592004; called by muse, mutect2
- XRRA1 | c.1790G>A p.R597K | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1258123686; called by muse, mutect2
- ZBED9 | c.2188C>A p.H730N | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV71729259; called by muse, mutect2
- ZC3H4 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs778540261; called by muse, mutect2, varscan2
- ZNF33B | c.2246A>G p.Y749C | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs145246304; called by muse, mutect2, varscan2
- ZNF735 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs753100490; called by muse, mutect2, varscan2
- ZNF780B | c.1695C>G p.F565L | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV55467018; called by muse, mutect2, varscan2
- ZNFX1 | c.5575G>T p.D1859Y | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV65600394; called by muse, mutect2, varscan2
- AASDHPPT | c.332A>T p.H111L | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.3614T>C p.V1205A | Missense Mutation (SNP) | VAF 54/462 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, varscan2
- ABCC8 | c.3558G>T p.R1186S | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ABCC8 | c.3558-1G>T p.X1186_splice | Splice Site (SNP) | VAF 36/286 reads (13%) | called by muse, mutect2, varscan2
- ADAM33 | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ADCY8 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD9 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- APBA2 | c.1867G>T p.G623C | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATF2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ATP9B | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BCL2A1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 48/381 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BOD1L1 | c.8624G>A p.R2875K | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C7orf26 | c.1112A>T p.D371V | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNG3 | c.594C>A p.H198Q | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CARD11 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- CARD11 | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASP8AP2 | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC178 | c.2494G>T p.E832* (on ENST00000383096 / NM_001105528.3; = p.E794* on NM_198995.3) | Nonsense Mutation (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- CCDC178 | c.2493G>T p.Q831H (on ENST00000383096 / NM_001105528.3; = p.Q793H on NM_198995.3) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CD80 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CDC7 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CDC73 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- CEP350 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- CFAP91 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL22A1 | c.4667G>T p.G1556V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A4 | c.3482T>C p.I1161T | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A3 | c.3193G>A p.V1065I | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- COLEC12 | c.954C>A p.H318Q | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- COPS2 | c.1107A>G p.I369M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CRYBG2 | c.4906G>T p.G1636C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CRYZ | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2
- CTRC | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX60L | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DEFB133 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2
- DISP1 | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 61/488 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DSG3 | c.2200G>T p.A734S | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- EBF3 | c.555-1G>T p.X185_splice | Splice Site (SNP) | VAF 24/189 reads (13%) | called by muse, mutect2, varscan2
- EFCAB6 | c.3257C>A p.T1086K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by mutect2, varscan2
- ELAVL4 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- EP400 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EPB41L3 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- EPS8L3 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ETV5 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 97/583 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- EVC2 | c.3598C>G p.R1200G | Missense Mutation (SNP) | VAF 49/588 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2
- EXOC2 | c.1992G>T p.Q664H | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- F7 | c.1130T>A p.V377E | Missense Mutation (SNP) | VAF 119/434 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM234B | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FCRL1 | c.52+5G>T | Splice Region (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- FGA | c.2016G>A p.W672* | Nonsense Mutation (SNP) | VAF 48/408 reads (12%) | called by muse, mutect2, varscan2
- FSHR | c.1747C>A p.L583I | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GPR42 | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 20/582 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- GRID2 | c.2256T>G p.N752K | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- GRPEL2 | c.575del p.P192Lfs*6 | Frame Shift Del (DEL) | VAF 37/249 reads (15%) | called by mutect2, pindel, varscan2
- GTF2IRD2 | c.2277G>A p.M759I | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.055); called by mutect2, varscan2
- HCN1 | c.1796C>A p.S599* | Nonsense Mutation (SNP) | VAF 37/244 reads (15%) | called by muse, varscan2
- HDAC10 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HGF | c.1101del p.T368Lfs*43 | Frame Shift Del (DEL) | VAF 35/382 reads (9%) | called by mutect2, pindel
- HTR2A | c.508T>A p.S170T | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFT27 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IL31RA | c.831G>T p.R277S | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- KCTD16 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- KIAA1109 | c.12149A>G p.Q4050R | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KIF1C | c.2230A>G p.M744V | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KPRP | c.965del p.G322Afs*49 | Frame Shift Del (DEL) | VAF 20/252 reads (8%) | called by mutect2, pindel
- LCP1 | c.54T>A p.F18L | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- LRFN2 | c.2336G>A p.G779D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, varscan2
- LRP1B | c.7168T>C p.C2390R | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRRC53 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LY6H | c.338C>A p.A113E | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- MACF1 | c.20704G>T p.D6902Y (on ENST00000372915; = p.D4947Y on NM_012090.5) | Missense Mutation (SNP) | VAF 23/152 reads (15%) | called by muse, mutect2, varscan2
- MAGEB5 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, varscan2
- MANBA | c.2465C>T p.S822L (on ENST00000642252; = p.S776L on NM_005908.4) | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAP1S | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCFD2 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 43/391 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- MEIS3 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- MPDZ | c.4303G>C p.A1435P | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A1 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- NAV3 | c.1386G>T p.L462F | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.676); called by muse, varscan2
- NAV3 | c.1837G>C p.A613P | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NAV3 | c.4075G>T p.D1359Y | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDUFB5 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKD2 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); called by muse, mutect2
- NLRP7 | c.1994C>A p.T665K | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OLR1 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR10G8 | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- OR10S1 | c.105del p.K35Nfs*26 | Frame Shift Del (DEL) | VAF 30/260 reads (12%) | called by pindel, varscan2
- OR10V1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR2A25 | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- OR2B11 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR4M1 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ORC1 | c.1080G>C p.K360N | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, varscan2
- ORC1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDH10 | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB15 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PEG3 | c.3080A>T p.E1027V | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PHF7 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PITX3 | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PKHD1 | c.8845G>A p.E2949K | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLAA | c.546_551delinsGT p.C183* | Frame Shift Del (DEL) | VAF 24/157 reads (15%) | called by pindel, varscan2*
- PLCB4 | c.3050T>C p.V1017A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, varscan2
- PLEC | c.11745G>C p.Q3915H (on ENST00000322810 / NM_201380.4; = p.Q3805H on NM_000445.5) | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEC | c.7722G>T p.Q2574H (on ENST00000322810 / NM_201380.4; = p.Q2464H on NM_000445.5) | Missense Mutation (SNP) | VAF 48/381 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PNISR | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2
- PNPLA8 | c.832G>T p.V278F | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- POM121L2 | c.2056C>A p.P686T | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PSMG2 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAF1 | c.340T>G p.W114G | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RAPGEF5 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRP2 | c.1483A>T p.M495L | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RGPD4 | c.2861G>C p.G954A | Missense Mutation (SNP) | VAF 46/610 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2
- RPAP3 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- RUBCN | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SASS6 | c.1100del p.G367Efs*7 | Frame Shift Del (DEL) | VAF 19/169 reads (11%) | called by mutect2, pindel, varscan2
- SDK2 | c.3106G>C p.G1036R | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SEMA5B | c.2878G>T p.A960S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEMG2 | c.64A>T p.M22L | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); called by muse, mutect2
- SH3GL3 | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC12A7 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC14A2 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC4A4 | c.1620T>A p.F540L (on ENST00000264485 / NM_001098484.3; = p.F496L on NM_003759.4) | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- SLC9A9 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- SLCO1B1 | c.22A>G p.N8D | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA16 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 60/544 reads (11%) | called by muse, mutect2
- STAT2 | c.1841G>T p.W614L | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCEAL6 | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TCEAL6 | c.65T>A p.V22E | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TDRD12 | c.2569C>T p.P857S (on ENST00000444215; = p.P862S on NM_001366102.1) | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TENM1 | c.5198G>A p.G1733E | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TENM4 | c.1731C>G p.I577M | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TLN1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.15); called by muse, mutect2
- TLR4 | c.2277T>A p.F759L (on ENST00000355622 / NM_138554.5; = p.F719L on NM_003266.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TMEM132E | c.2591C>A p.A864E (on ENST00000321639; = p.A954E on NM_001304438.2) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TPCN1 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPC1 | c.345G>C p.L115F | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TTC3 | c.2373C>G p.D791E | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- TTLL6 | c.1813G>T p.V605F (on ENST00000393382 / NM_001130918.3; = p.V298F on NM_173623.3) | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTN | c.62135-4C>A | Splice Region (SNP) | VAF 44/339 reads (13%) | called by muse, mutect2, varscan2
- UBR5 | c.7578G>T p.L2526F | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- ULBP2 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 19/158 reads (12%) | called by muse, varscan2
- UNC13B | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- UNC5B | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2
- UNC5D | c.2835C>A p.F945L | Missense Mutation (SNP) | VAF 41/586 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.899); called by muse, mutect2
- USP36 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, varscan2
- USP5 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP8 | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2
- VLDLR | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 37/375 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- WDR59 | c.2578G>C p.D860H | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- XRRA1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- ZBTB7B | c.121dup p.Q41Pfs*4 (on ENST00000292176; = p.Q75Pfs*4 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/256 reads (11%) | called by mutect2, pindel, varscan2
- ZFYVE26 | c.7124G>A p.C2375Y | Missense Mutation (SNP) | VAF 66/383 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZFYVE26 | c.6714G>C p.L2238F | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ZNF253 | c.288A>G p.I96M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF280C | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF679 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ZNF799 | c.573G>C p.Q191H | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF804A | c.3458C>A p.P1153Q | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- AC004997.1 | c.1029G>A p.V343= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- ADAM19 | c.2484G>A p.T828= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs374925196, COSV99976342; called by muse, mutect2, varscan2
- ADGRL3 | c.3381T>C p.C1127= (on ENST00000506720 / NM_001322402.2; = p.C1059= on NM_015236.6) | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs749363474; called by muse, mutect2, varscan2
- ADGRV1 | c.6552C>G p.A2184= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2, varscan2
- ANK1 | c.3879G>T p.L1293= | Silent (SNP) | VAF 529/1000 reads (53%) | called by muse, mutect2, varscan2
- ANK1 | c.660C>T p.N220= | Silent (SNP) | VAF 53/980 reads (5%) | catalogued as rs773555671; ClinVar: uncertain significance; called by muse, mutect2
- ARHGAP1 | c.198C>T p.D66= | Silent (SNP) | VAF 56/452 reads (12%) | catalogued as rs1455641224; called by muse, mutect2, varscan2
- ARHGAP30 | c.1491C>T p.A497= | Silent (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- BABAM2 | c.234A>G p.P78= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as rs769796449; called by muse, mutect2, varscan2
- BCL2A1 | c.168G>A p.L56= | Silent (SNP) | VAF 51/388 reads (13%) | called by muse, mutect2, varscan2
- BCLAF3 | c.1539A>G p.P513= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- BRINP2 | c.2181G>A p.V727= | Silent (SNP) | VAF 35/218 reads (16%) | catalogued as COSV64180199; called by muse, mutect2, varscan2
- CACNA1G | c.556C>A p.R186= | Silent (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- CCDC81 | c.1746C>T p.C582= (on ENST00000445632 / NM_001156474.2; = p.C492= on NM_021827.4) | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as rs1415787981; called by muse, mutect2
- CDH19 | c.189C>T p.I63= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs750212333, COSV100050976, COSV100051987; called by mutect2, varscan2
- DACT1 | c.2391G>A p.T797= | Silent (SNP) | VAF 56/257 reads (22%) | catalogued as rs776874389, COSV60023007; called by muse, mutect2, varscan2
- DCDC1 | c.3804T>C p.N1268= (on ENST00000597505 / NM_001367979.1; = p.N375= on NM_020869.3) | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100337925; called by muse, mutect2, varscan2
- DEFB133 | c.171C>A p.A57= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- EMP2 | c.450C>T p.F150= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs767283646, COSV63995944; called by muse, mutect2, varscan2
- ENPEP | c.1383T>A p.I461= | Silent (SNP) | VAF 21/212 reads (10%) | called by muse, mutect2
- EPB41 | c.1389C>T p.I463= (on ENST00000343067 / NM_001166005.2; = p.I254= on NM_004437.4) | Silent (SNP) | VAF 34/310 reads (11%) | catalogued as rs1307395143, COSV58049264; called by muse, mutect2, varscan2
- FAIM2 | c.261C>G p.L87= | Silent (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- FBN3 | c.6270G>A p.E2090= | Silent (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- FCGBP | c.5589G>A p.T1863= | Silent (SNP) | VAF 84/822 reads (10%) | catalogued as rs1227400473; called by muse, mutect2, varscan2
- FCRLA | c.486G>C p.G162= (on ENST00000367959; = p.G139= on NM_032738.4) | Silent (SNP) | VAF 32/232 reads (14%) | called by muse, mutect2, varscan2
- FREM3 | c.5517C>A p.A1839= | Silent (SNP) | VAF 36/343 reads (10%) | called by muse, mutect2, varscan2
- FTMT | c.87G>T p.P29= | Silent (SNP) | VAF 24/131 reads (18%) | called by muse, mutect2, varscan2
- GFPT1 | c.1851T>C p.Y617= (on ENST00000357308 / NM_001244710.2; = p.Y599= on NM_002056.4) | Silent (SNP) | VAF 40/315 reads (13%) | catalogued as rs377155851; ClinVar: likely benign; called by muse, mutect2, varscan2
- GGTLC1 | c.603A>G p.Q201= | Silent (SNP) | VAF 60/545 reads (11%) | called by muse, mutect2, varscan2
- GSDME | c.1308G>A p.L436= | Silent (SNP) | VAF 72/506 reads (14%) | catalogued as rs748341598, COSV61652557; called by muse, mutect2, varscan2
- H1-10 | c.435G>A p.K145= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- IBA57 | c.246T>C p.S82= | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- IL1RL1 | c.1593G>T p.V531= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- IL36A | c.99C>A p.V33= | Silent (SNP) | VAF 27/261 reads (10%) | catalogued as COSV52082766; called by muse, mutect2, varscan2
- INPP5D | c.1269G>A p.T423= (on ENST00000445964 / NM_001017915.3; = p.T422= on NM_005541.5) | Silent (SNP) | VAF 49/391 reads (13%) | catalogued as rs377021577, COSV100856504; called by muse, mutect2, varscan2
- JAM2 | c.786G>A p.Q262= | Silent (SNP) | VAF 25/220 reads (11%) | called by muse, mutect2, varscan2
- KCNIP3 | c.489C>A p.V163= | Silent (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- KHNYN | c.525T>C p.H175= | Silent (SNP) | VAF 27/212 reads (13%) | called by muse, mutect2, varscan2
- KLHL34 | c.438G>A p.T146= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, varscan2
- KLHL34 | c.402C>T p.A134= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, varscan2
- KMT5B | c.1467C>T p.P489= | Silent (SNP) | VAF 32/289 reads (11%) | called by muse, mutect2, varscan2
- KRT5 | c.420C>T p.I140= | Silent (SNP) | VAF 39/256 reads (15%) | called by muse, mutect2, varscan2
- LRRC7 | c.225G>C p.V75= (on ENST00000651989 / NM_001370785.2; = p.V42= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/349 reads (13%) | catalogued as COSV50408788; called by muse, mutect2, varscan2
- MACF1 | c.20703G>T p.R6901= (on ENST00000372915; = p.R4946= on NM_012090.5) | Silent (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- MARK2 | c.2139G>A p.E713= (on ENST00000402010 / NM_001039469.2; = p.E649= on NM_004954.5) | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- MCM7 | c.243A>G p.V81= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as rs372198296, COSV100384750; called by muse, mutect2, varscan2
- NEURL1 | c.1713C>T p.Y571= | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2
- NGFR | c.1044G>A p.E348= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV50803757; called by muse, mutect2, varscan2
- NR1H4 | c.375C>T p.G125= (on ENST00000551379 / NM_001206993.2; = p.G115= on NM_005123.4) | Silent (SNP) | VAF 40/302 reads (13%) | catalogued as rs372358310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.567C>A p.V189= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV68012559; called by muse, mutect2, varscan2
- NXPE4 | c.912A>G p.K304= (on ENST00000375478 / NM_001077639.2; = p.K20= on NM_017678.3) | Silent (SNP) | VAF 39/284 reads (14%) | called by muse, mutect2, varscan2
- OR1G1 | c.522C>A p.I174= | Silent (SNP) | VAF 54/371 reads (15%) | called by muse, mutect2, varscan2
- OR7E24 | c.258G>A p.L86= | Silent (SNP) | VAF 46/407 reads (11%) | called by muse, mutect2, varscan2
- OSBPL7 | c.2238G>C p.L746= | Silent (SNP) | VAF 29/213 reads (14%) | called by muse, mutect2, varscan2
- PANX3 | c.696G>T p.L232= | Silent (SNP) | VAF 41/288 reads (14%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1890G>A p.E630= | Silent (SNP) | VAF 34/235 reads (14%) | catalogued as rs376345503; called by muse, mutect2, varscan2
- PCDHGA9 | c.582G>T p.L194= | Silent (SNP) | VAF 20/160 reads (13%) | called by muse, varscan2
- PCDHGB2 | c.1887G>T p.A629= | Silent (SNP) | VAF 37/227 reads (16%) | called by muse, mutect2, varscan2
- PDPR | c.2475G>T p.G825= | Silent (SNP) | VAF 30/573 reads (5%) | called by muse, mutect2
- PLCE1 | c.3543G>A p.K1181= | Silent (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2, varscan2
- PLEC | c.12282C>A p.I4094= (on ENST00000322810 / NM_201380.4; = p.I3984= on NM_000445.5) | Silent (SNP) | VAF 72/529 reads (14%) | called by muse, mutect2, varscan2
- PPP1R9A | c.1635T>G p.A545= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, varscan2
- PTPN3 | c.1779G>C p.V593= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2
- PTPRB | c.5139G>A p.V1713= | Silent (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2
- R3HDM1 | c.1008T>G p.A336= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.1440C>T p.L480= | Silent (SNP) | VAF 32/292 reads (11%) | called by muse, mutect2, varscan2
- ROBO4 | c.333C>G p.V111= | Silent (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- RTP5 | c.495C>T p.N165= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs761978952, COSV100574818; called by mutect2, varscan2
- SHISA8 | c.237G>T p.P79= (on ENST00000457093; = p.P112= on NM_001207020.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- SI | c.2268C>T p.Y756= | Silent (SNP) | VAF 47/281 reads (17%) | catalogued as rs746566120; called by muse, mutect2, varscan2
- SLC17A1 | c.312A>C p.I104= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs143996965; called by muse, mutect2, varscan2
- SLC22A11 | c.1644C>A p.T548= | Silent (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- SLC35E1 | c.54G>A p.A18= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as rs913045182; called by muse, mutect2
- SLX4IP | c.906G>A p.A302= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs757894309, COSV100570599; called by muse, mutect2, varscan2
- SNRNP200 | c.5058G>A p.Q1686= | Silent (SNP) | VAF 68/456 reads (15%) | called by muse, mutect2, varscan2
- SOX17 | c.1005C>G p.P335= | Silent (SNP) | VAF 88/401 reads (22%) | catalogued as rs988347799; called by muse, mutect2, varscan2
- SPATA2L | c.936G>A p.L312= | Silent (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- SPATA31A6 | c.888A>G p.S296= | Silent (SNP) | VAF 98/764 reads (13%) | called by muse, mutect2, varscan2
- STRIP2 | c.1374C>T p.P458= | Silent (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- SUPT5H | c.933C>T p.I311= | Silent (SNP) | VAF 38/308 reads (12%) | catalogued as rs777840770; called by muse, mutect2, varscan2
- TESPA1 | c.601C>T p.L201= (on ENST00000316577 / NM_001098815.3; = p.L63= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 23/261 reads (9%) | called by muse, mutect2
- TIMM44 | c.1356C>G p.L452= | Silent (SNP) | VAF 45/345 reads (13%) | called by muse, mutect2, varscan2
- TMEM64 | c.198C>G p.L66= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- TNS1 | c.4164G>A p.E1388= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV99412154; called by muse, mutect2, varscan2
- TNS1 | c.4089G>A p.L1363= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- TRMT10C | c.1155G>A p.L385= | Silent (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.31944T>A p.T10648= (on ENST00000591111; = p.T9721= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- UNG | c.237C>T p.A79= (on ENST00000242576 / NM_080911.3; = p.A70= on NM_003362.4) | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs765568201; called by muse, mutect2, varscan2
- USP38 | c.609G>A p.Q203= | Silent (SNP) | VAF 35/253 reads (14%) | called by muse, mutect2, varscan2
- ZNF878 | c.84C>G p.L28= | Silent (SNP) | VAF 21/206 reads (10%) | called by muse, mutect2, varscan2
- AC068633.1 | n.311A>T | RNA (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
- C22orf34 | n.193C>T | RNA (SNP) | VAF 22/162 reads (14%) | catalogued as rs1182561635; called by muse, mutect2, varscan2
- CACNA1S | c.-10C>G | 5'UTR (SNP) | VAF 31/298 reads (10%) | called by muse, mutect2, varscan2
- CCDC107 | chr9:35657890 G>T | 5'Flank (SNP) | VAF 24/217 reads (11%) | called by muse, mutect2, varscan2
- CCDC88A | c.882+14A>T | Intron (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- CRB1 | c.1171+51G>T | Intron (SNP) | VAF 42/293 reads (14%) | called by mutect2, varscan2
- CRELD1 | c.1049-359G>A | Intron (SNP) | VAF 47/338 reads (14%) | called by muse, mutect2, varscan2
- DCC | c.-8G>T | 5'UTR (SNP) | VAF 55/428 reads (13%) | catalogued as rs564701541; called by muse, mutect2, varscan2
- DENND6B | c.702+18G>T | Intron (SNP) | VAF 21/154 reads (14%) | called by muse, mutect2, varscan2
- ECRG4 | c.80-889C>G | Intron (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- FCER1A | c.-15G>T | 5'UTR (SNP) | VAF 20/130 reads (15%) | called by muse, varscan2
- FCRL5 | c.307+665A>G | Intron (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- FLT4 | c.3807+27C>T | Intron (SNP) | VAF 29/193 reads (15%) | catalogued as rs1420320560; called by muse, mutect2, varscan2
- GABRB3 | c.-16G>T | 5'UTR (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- GALNTL6 | c.139-177178C>A | Intron (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- GRK2 | c.*940C>T | 3'UTR (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2
- HM13 | c.1035-1024A>G | Intron (SNP) | VAF 16/146 reads (11%) | called by muse, varscan2
- IGKV2OR22-4 | n.147C>T | RNA (SNP) | VAF 35/272 reads (13%) | catalogued as rs1416027482; called by muse, mutect2, varscan2
- LMBR1 | c.*2906C>T | 3'UTR (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- LRRK2 | c.3496+1629T>A | Intron (SNP) | VAF 24/214 reads (11%) | called by muse, mutect2, varscan2
- MAN1A2 | c.*335G>A | 3'UTR (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- MCOLN1 | c.-39C>G | 5'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- MIR520F | n.73G>T | RNA (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- MTFR1L | c.-21C>G | 5'UTR (SNP) | VAF 35/251 reads (14%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54753C>A | Intron (SNP) | VAF 14/87 reads (16%) | catalogued as COSV54235137; called by muse, varscan2
- NKD1 | c.-88G>A | 5'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- NKX6-3 | c.553-610G>A | Intron (SNP) | VAF 20/310 reads (6%) | catalogued as rs540879919; called by muse, mutect2
- NODAL | c.891+48G>A | Intron (SNP) | VAF 35/138 reads (25%) | called by muse, mutect2, varscan2
- NSUN5 | c.*132A>G | 3'UTR (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2
- NXF5 | n.586G>A | RNA (SNP) | VAF 46/170 reads (27%) | called by muse, mutect2, varscan2
- OSTCP1 | n.244G>A | RNA (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2
- PLEKHB1 | c.248-314G>A | Intron (SNP) | VAF 18/141 reads (13%) | catalogued as rs1031653176, COSV57050728; called by muse, mutect2, varscan2
- RNF170 | c.*2673C>T | 3'UTR (SNP) | VAF 22/478 reads (5%) | called by muse, mutect2
- RUNX1T1 | c.88+13258G>T | Intron (SNP) | VAF 16/122 reads (13%) | catalogued as rs757205965; called by muse, mutect2
- SPATA31C2 | n.2461G>T | RNA (SNP) | VAF 69/497 reads (14%) | called by muse, mutect2, varscan2
- TIGIT | chr3:114293959 C>G | 5'Flank (SNP) | VAF 34/344 reads (10%) | catalogued as COSV67328771; called by muse, mutect2, varscan2
- TNPO2 | c.-13-358C>T | Intron (SNP) | VAF 22/117 reads (19%) | catalogued as COSV63509647; called by muse, mutect2, varscan2
- TOX2 | c.907-928A>G | Intron (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- TRDN | c.794-1312G>A | Intron (SNP) | VAF 33/244 reads (14%) | catalogued as rs986599873; called by muse, mutect2, varscan2
- TRDN | c.484+1115C>A | Intron (SNP) | VAF 23/195 reads (12%) | called by muse, varscan2
- WT1 | chr11:32439168 C>A | 5'Flank (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- ZBP1 | c.1094-2321G>T | Intron (SNP) | VAF 15/124 reads (12%) | catalogued as rs1423965150; called by muse, mutect2, varscan2
- ZEB2 | c.73+5157A>G | Intron (SNP) | VAF 31/241 reads (13%) | called by muse, mutect2, varscan2
- ZNF275 | c.32-845T>C | Intron (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- ZNF793 | c.*4610G>A | 3'UTR (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
